FM case AD17759 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Primary site: Bronchus and lung.
https://portal.gdc.cancer.gov/cases/b6c018b1-6183-412a-a484-662f625b790c

Male, 37.9 years: diagnosis not reported by GDC of the lung. Tumor nuclei on the sequenced sample's slide: 60% (pathologist estimate recorded by GDC). Sample type: Tumor.
